Somatic mutation profile of tumor specimen TCGA-HW-A5KJ-01A (aliquot TCGA-HW-A5KJ-01A-12D-A27K-08) from TCGA case TCGA-HW-A5KJ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 68.4 years (24,966 days).
Specimen TCGA-HW-A5KJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecf4bd96-8b72-4925-aca6-1a6a4a7adae5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-A5KJ-10A (Blood Derived Normal), aliquot TCGA-HW-A5KJ-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20882e6f-7242-471c-8e13-7173a307b6ed

The open-access MAF lists 42 somatic variants for this specimen: 35 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, In Frame Del 9, Frame Shift Del 8, Silent 6, Splice Site 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 40/91 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1067_1069del p.S356del | In Frame Del (DEL) | VAF 16/36 reads (44%) | hotspot (GDC flag); called by pindel, varscan2
- AC008676.3 | c.154_156del p.E52del | In Frame Del (DEL) | VAF 38/121 reads (31%) | catalogued as rs1456863039; called by pindel, varscan2
- ADAMTS1 | c.2284A>T p.R762W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV53170175; called by muse, mutect2, varscan2
- BAHD1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs150307966; called by muse, mutect2, varscan2
- CA5A | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770900204, COSV59240507; called by muse, mutect2, varscan2
- CCDC88B | c.1853A>C p.Q618P | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.069); catalogued as rs142814776; called by muse, mutect2, varscan2
- EPB41L2 | c.129_131del p.E44del | In Frame Del (DEL) | VAF 32/112 reads (29%) | catalogued as rs1473717538; called by pindel, varscan2
- ERG | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.864); catalogued as COSV55731548; called by muse, mutect2, varscan2
- KLHDC10 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as COSV59051560; called by muse, mutect2
- KSR1 | c.1927C>T p.R643W (on ENST00000644974 / NM_001367810.1; = p.R528W on NM_014238.2) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52032149; called by muse, mutect2, varscan2
- LRRC8B | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as rs375681290; called by muse, mutect2, varscan2
- MAVS | c.293-2A>G p.X98_splice | Splice Site (SNP) | VAF 51/142 reads (36%) | catalogued as COSV63926858; called by muse, mutect2, varscan2
- MS4A12 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV50014428; called by muse, mutect2
- NEFL | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55336932; called by muse, mutect2
- PIGW | c.561_563del p.R188del | In Frame Del (DEL) | VAF 45/176 reads (26%) | catalogued as rs1321655347; called by pindel, varscan2
- RAB3GAP1 | c.2417_2419del p.K806del | In Frame Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs752726257; called by pindel, varscan2
- SCN2A | c.4976C>A p.A1659E | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51839926; called by muse, mutect2, varscan2
- SZT2 | c.9017_9020del p.K3006Sfs*33 (on ENST00000634258 / NM_001365999.1; = p.K2949Sfs*33 on NM_015284.4) | Frame Shift Del (DEL) | VAF 33/54 reads (61%) | catalogued as rs756625074; called by mutect2, pindel, varscan2
- UHRF1BP1L | c.1181A>G p.H394R | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as rs1165160357, COSV54437025; called by muse, mutect2, varscan2
- UNC13A | c.2580G>T p.E860D | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV53194719, COSV53207717; called by muse, mutect2, varscan2
- ZNF614 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.676); catalogued as rs368927052; called by muse, mutect2, varscan2
- ALDH1L2 | c.269_271del p.E90del | In Frame Del (DEL) | VAF 18/94 reads (19%) | called by pindel, varscan2
- CLEC9A | c.23_35del p.T8Rfs*25 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- FAM91A1 | c.367+1_367+2del p.X123_splice | Splice Site (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- GALNTL6 | c.1700_1702del p.K567del | In Frame Del (DEL) | VAF 20/78 reads (26%) | called by pindel, varscan2
- KAT6B | c.3606_3609del p.T1203Rfs*21 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- KMT2E | c.1040_1041del p.K347Rfs*5 | Frame Shift Del (DEL) | VAF 37/83 reads (45%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.5166_5167+2del p.X1722_splice | Splice Site (DEL) | VAF 14/76 reads (18%) | called by pindel, varscan2
- OR14A16 | c.192_193del p.S65Ffs*54 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- PI4KB | c.2318_2319del p.K773Rfs*9 (on ENST00000368873 / NM_001369623.1; = p.K785Rfs*9 on NM_002651.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/109 reads (39%) | called by mutect2, pindel, varscan2
- SP3 | c.2098_2099del p.I700* | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | called by pindel, varscan2
- SPECC1L | c.1864_1865del p.L622Gfs*2 | Frame Shift Del (DEL) | VAF 42/150 reads (28%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.1847_1849del p.S616del (on ENST00000474710 / NM_001164342.2; = p.S543del on NM_015642.6 and 4 other RefSeq transcripts) | In Frame Del (DEL) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- ZYX | c.418_420del p.K140del | In Frame Del (DEL) | VAF 65/357 reads (18%) | called by mutect2, pindel, varscan2
- DDIAS | c.1503A>T p.G501= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV61271988; called by muse, mutect2, varscan2
- FLG | c.6063C>T p.G2021= | Silent (SNP) | VAF 30/1147 reads (3%) | catalogued as COSV64237679, COSV64241417; called by muse, mutect2
- RASSF9 | c.318G>A p.E106= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs1248722832, COSV63433511; called by muse, mutect2
- SLIT1 | c.2307C>T p.D769= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs141130521; called by muse, mutect2, varscan2
- SLIT3 | c.4551C>T p.C1517= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs375394267; called by muse, mutect2, varscan2
- SOX10 | c.309C>T p.H103= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1267906231, COSV61005309; called by muse, mutect2
- BABAM2 | c.1089-11157_1089-11156del | Intron (DEL) | VAF 50/188 reads (27%) | called by pindel, varscan2
